Somatic mutation profile of tumor specimen MP2PRT-PATETU-TMP1-A (aliquot MP2PRT-PATETU-TMP1-A-1-0-D-A80J-36) from MP2PRT case MP2PRT-PATETU, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.5 years (2,377 days).
Specimen MP2PRT-PATETU-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ff047526-7c16-4d42-8174-870d3c7d72cc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATETU-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATETU-NB1-A-1-0-D-A80J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b77910c-8abd-4c4b-b236-d614aa5a87d6

The open-access MAF lists 21 somatic variants for this specimen: 17 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 14, Silent 3, Frame Shift Ins 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.2176G>A p.E726K | Missense Mutation (SNP) | VAF 18/189 reads (10%) | hotspot (GDC flag); SIFT tolerated (0.36); PolyPhen benign (0.396); catalogued as rs867262025, CM126693, COSV55875460; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- IGKC | c.151A>G p.N51D | Missense Mutation (SNP) | VAF 64/248 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as rs770747924; called by muse, varscan2
- PHLDB2 | c.1235G>A p.R412Q | Missense Mutation (SNP) | VAF 186/396 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.153); catalogued as rs563713509; called by muse, mutect2, varscan2
- PXK | c.1493C>T p.T498M | Missense Mutation (SNP) | VAF 70/447 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.994); catalogued as rs760466508; called by muse, mutect2, varscan2
- SYK | c.1024C>T p.P342S | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV65330725; called by muse, varscan2
- TTN | c.6358C>T p.R2120W (on ENST00000591111; = p.R2074W on NM_003319.4) | Missense Mutation (SNP) | VAF 190/410 reads (46%) | PolyPhen probably damaging (0.96); catalogued as rs116158152, COSV59904099; ClinVar: uncertain significance; called by muse, varscan2
- UNC45B | c.245G>A p.R82Q | Missense Mutation (SNP) | VAF 185/398 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs762182255, COSV52097749, COSV99269050; called by muse, mutect2, varscan2
- YJU2 | c.550C>T p.R184W | Missense Mutation (SNP) | VAF 44/500 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.729); catalogued as rs755654352; called by muse, mutect2
- AOPEP | c.1072G>T p.D358Y | Missense Mutation (SNP) | VAF 36/323 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- IKZF2 | c.457G>C p.G153R | Missense Mutation (SNP) | VAF 28/457 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- MED12 | c.6494C>T p.T2165I | Missense Mutation (SNP) | VAF 174/178 reads (98%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- MYO16 | c.5545C>A p.L1849M | Missense Mutation (SNP) | VAF 165/349 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- PIK3R1 | c.1734_1735insGA p.Q579Dfs*4 (on ENST00000521381 / NM_181523.3; = p.Q309Dfs*4 on NM_181504.4) | Frame Shift Ins (INS) | VAF 36/297 reads (12%) | called by mutect2, pindel*, varscan2*
- RGMB | c.25A>G p.S9G (on ENST00000513185 / NM_001366508.1; = p.S50G on NM_001012761.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 250/775 reads (32%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0); called by muse, varscan2
- SMOC1 | c.844_847dup p.T283Rfs*12 | Frame Shift Ins (INS) | VAF 97/221 reads (44%) | called by mutect2, pindel, varscan2
- WT1 | c.685_686insC p.G229Afs*24 | Frame Shift Ins (INS) | VAF 61/392 reads (16%) | called by mutect2, pindel, varscan2
- ZFHX2 | c.2341A>G p.K781E | Missense Mutation (SNP) | VAF 66/497 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- H4C2 | c.309T>C p.G103= | Silent (SNP) | VAF 72/135 reads (53%) | catalogued as rs773305848; called by muse, varscan2
- RBM47 | c.111G>A p.A37= | Silent (SNP) | VAF 74/790 reads (9%) | catalogued as rs749676324; called by muse, mutect2
- SOHLH1 | c.555G>A p.A185= | Silent (SNP) | VAF 51/509 reads (10%) | catalogued as rs776969611, COSV53680720; called by muse, mutect2, varscan2
- IGLV6-57 | chr22:22196276 ins CGCTCC | 3'Flank (INS) | VAF 27/170 reads (16%) | called by pindel, varscan2*
